Somatic mutation profile of tumor specimen TCGA-DJ-A4UP-01A (aliquot TCGA-DJ-A4UP-01A-11D-A257-08) from TCGA case TCGA-DJ-A4UP, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 15.5 years (5,655 days).
Specimen TCGA-DJ-A4UP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b9cb5bd-f464-4aa5-b5d4-02a9e09bc418.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A4UP-10A (Blood Derived Normal), aliquot TCGA-DJ-A4UP-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5c75622-fe0e-42f5-9768-9330f507b61f

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMDEC1 | c.239T>C p.M80T | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV56475713; called by muse, mutect2
- DHX16 | c.832G>C p.D278H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV64564462; called by muse, mutect2, varscan2
- CDC5L | c.552C>G p.A184= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV101014834; called by mutect2, varscan2
- ZNF74 | c.399G>A p.P133= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as rs1195659276, COSV62621568; called by muse, mutect2
